Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6HX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6HX-01A (Primary Tumor).

SBX: Male
D.O.B.:
MRN #:
Ref Phys:

SPECIMEN IN

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Bilateral pelvic lymph node dissection:
Four benign lymph nodes (0/4).
- B. Radical prostatectomy:
Carcinoma.
- Tumor Characteristics:**
- Specimen integrity: Specimen intact.
- Histologic type: Adenocarcinoma, usual type.
- Prostate size: 36 grams, 4.2 x 3.5 x 3.2 cm.
- Tumor quantitation: 5-10%.
- Gleason grade:
- Primary pattern: 4/5.
- Secondary pattern: 3/5.
- Tertiary pattern: 5/5.
- Total Gleason score: 7/10.
- Perineural invasion: Present.
- Extraprostatic extension: Not identified.
- Seminal vesicle involvement: Not identified.
- Lymphovascular space invasion: Not identified.
- High grade PIN: Present.
- Treatment effect: Not identified.

Surgical Margin Status:

Margins uninvolved.

Lymph Node Status:

- Total number of lymph nodes received: Four.
- Total number of lymph nodes containing metastatic carcinoma: None (0/4).
- Other:**
- Other significant findings: None.
- pTN stage: pT2c N0.

C6CF ICD-O-3

Adenocarcinoma, acinar
8140/3

path
Adenocarcinoma NOS
8140/3

Site: Prostate NOS
C61.9

JW 6/12/13

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: History prostate cancer
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right and left pelvic lymph nodes
B. Prostate, right blue, left black

HPV A Discrepancy		☒

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is received in formalin labeled and right and left pelvic lymph nodes, is an 8.1 x 6.2 x 1.8 cm mass of nodular yellow adipose tissue. On sectioning and palpation, four lymph node candidates are identified ranging from 0.5 x 0.4 x 0.2 cm to 4.8 x 1.5 x 0.7 cm. The three largest nodules are sectioned to show predominantly yellow glistening fatty tissue. One displays a gritty pink cut surface. The nodules are entirely submitted as follows: 1 and 2—one nodule bisected; 3 to 7—one nodule sectioned; 8—one intact nodule; 9 to 15—one nodule sectioned.

B. Container B is received in formalin labeled and prostate, is a 36 gram radical prostatectomy specimen, 4.2 x 3.5 x 3.2 cm. The right side is inked blue and the left side black. The specimen has been previously incised on the posterior aspect and is sampled for research. The specimen is further sectioned to posterior to show a 0.7 cm pale yellow palpable lesion in the right posterior aspect of the mid level.

The seminal vesicles together measure 4.5 x 1.5 x 0.7 cm. The cut surfaces are gray, cystic and without lesion.

Representative sections are submitted as follows: 1 and 2—apical margin; 3—vesicle margin; 4—distal left lateral; 5—distal right lateral; 6—distal right lateral; 7—distal left posterior; 8—mid left lateral; 9—mid right lateral; 10—mid right posterior; 11—mid left posterior; 12—proximal left lateral; 13—proximal right lateral; 14—proximal right posterior; 15—proximal left posterior; 16—origin of seminal vesicles; 17—

Source: NCI Genomic Data Commons file 5070901d-059b-4b37-b42b-a42267bb2c43 (TCGA-HC-A6HX.0E22E3BE-B28B-40CC-83F9-9B59593B7187.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).